Gene-level copy-number profile of tumor specimen TCGA-BT-A20V-01A from TCGA case TCGA-BT-A20V, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 59.0 years (21,551 days).
Specimen TCGA-BT-A20V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.66c84039-75c1-4322-9189-4e665dda9db0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A20V-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/8e4f80d6-6efa-41bf-a374-31739667e47f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 293; copy number 2: 20,243; copy number 3: 15,352; copy number 4: 13,337; copy number 5: 5,085; copy number 6: 2,357; copy number 7: 1,007; copy number 8: 313; copy number 9: 299; copy number 10: 289; copy number 11: 218; copy number 12: 276; copy number 13: 11; copy number 14: 406; copy number 15: 15; copy number 16: 117; copy number 17: 29; copy number 18: 3; copy number 19: 17; copy number 20: 1; copy number 21: 84; copy number 26: 54.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A20V-01A-11D-A14V-01): tumor purity 0.66, ploidy 3.37, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 10,487 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–10,181,239, 344 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:244,352,635–248,181,067, 123 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–90,367,699, 1,621 genes, copy number 6–8 (broad region; genes not listed).
- chr2:120,686,635–126,203,372, 42 genes, copy number 5: AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1, CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P, AC097499.2, LINC01889, AC097499.1, LINC01941, AC142116.2.
- chr2:131,591,752–134,959,342, 61 genes, copy number 6 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 5–9 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 8–13 (broad region; genes not listed).
- chr7:12,726,152–36,724,549, 402 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:37,326,575–39,730,065, 71 genes, copy number 6–15 (within-gene range 3–15) (broad region; genes not listed).
- chr8:69,110,513–101,307,428, 528 genes, copy number 5 (broad region; genes not listed).
- chr8:102,154,550–145,066,685, 650 genes, copy number 5 (broad region; genes not listed).
- chr9:5,091,093–7,961,224, 63 genes, copy number 10–26 (broad region; genes not listed).
- chr9:8,700,595–8,864,772, 4 genes, copy number 5: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1.
- chr9:18,573,306–21,187,671, 49 genes, copy number 15–26 (within-gene range 2–26): MIR3152, RN7SKP258, RAP1BP1, SAXO1, AL356000.1, RRAGA, HAUS6, SCARNA8, RNU6-264P, Y_RNA, PLIN2, AL161909.1, DENND4C, AL161909.2, AL391834.1, AL391834.2, RPS6, NDUFA5P3, AL391834.3, ACER2, AL158206.1, MAP1LC3BP1, SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4.
- chr10:42,782,795–45,453,121, 77 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr10:111,498,191–112,356,574, 7 genes, copy number 5 (within-gene range 4–5): RPS6P15, AL136119.1, GPAM, TECTB, MIR6715B, MIR6715A, GUCY2GP.
- chr11:57,542,641–62,260,549, 214 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr11:127,021,736–135,075,908, 113 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:66,767–68,451,663, 1,736 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).
- chr15:19,878,555–26,477,840, 299 genes, copy number 6–17 (broad region; genes not listed).
- chr15:26,557,598–26,658,763, 2 genes, copy number 17: AC009878.1, AC011196.1.
- chr15:56,244,009–56,445,997, 1 gene, copy number 11 (within-gene range 3–11): TEX9.
- chr15:56,274,530–56,629,592, 7 genes, copy number 11 (within-gene range 3–11): RNU6-1287P, HMGB1P33, AC084782.1, AC084782.2, MNS1, AC084782.3, AC090518.1.
- chr15:85,380,571–85,749,358, 1 gene, copy number 14 (within-gene range 4–14): AKAP13.
- chr15:85,579,046–88,568,562, 38 genes, copy number 14: AC087286.3, AC087286.2, AC087286.1, RNU6-1280P, AC087286.4, AC021739.3, AC021739.2, AC021739.4, LINC02883, KLHL25, MIR1276, AC021739.1, RNU6-231P, MIR548AP, AC104229.1, LINC01584, AGBL1, RNA5SP400, AC016180.2, AC016180.1, AGBL1-AS1, AC012229.1, AC016987.2, AC016987.1, AC078905.1, AC020687.1, RNU6-185P, LINC00052, AC103871.1, NTRK3, MED28P6, NTRK3-AS1, MRPL46, AC013489.1, MRPS11, AC013489.3, DET1, AC013489.2.
- chr16:66,988,589–76,928,169, 350 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:77,657,174–78,066,761, 11 genes, copy number 5: AC092724.1, NUDT7, AC092134.1, AC092134.3, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr16:78,123,243–78,355,834, 5 genes, copy number 5: AC079414.3, AC009044.1, WWOX-AS1, AC106743.1, LSM3P5.
- chr16:79,016,136–79,809,716, 16 genes, copy number 5 (within-gene range 4–5): AC009145.4, AC009145.3, AC009145.1, AC009145.2, AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3, AC009159.1, AC009159.4, LINC01229, MAFTRR.
- chr16:87,492,555–90,222,851, 111 genes, copy number 5 (broad region; genes not listed).
- chr18:47,390–15,330,282, 376 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–32,485,895, 90 genes, copy number 6–12 (broad region; genes not listed).
- chr20:7,633,562–25,752,776, 317 genes, copy number 7–21 (broad region; genes not listed).
- chr20:30,484,925–36,894,235, 218 genes, copy number 7–12 (broad region; genes not listed).
- chr20:39,655,325–40,043,889, 5 genes, copy number 6–21: AL132981.1, AL118523.1, HSPE1P1, LINC01370, AL133419.1.
- chr22:16,503,304–16,871,126, 25 genes, copy number 12: CHEK2P4, AP000547.2, AP000547.1, KCNMB3P1, CCT8L2, AP000547.4, FABP5P11, TPTEP1, AP000547.3, AP000365.1, SLC25A15P5, PARP4P3, ANKRD62P1-PARP4P3, ANKRD62P1, AC005301.1, VWFP1, AC005301.2, LINC01665, XKR3, HSFY1P1, GPM6BP3, AC007064.4, AC007064.3, ZNF402P, AC007064.2.

Autosomal genes at a single copy (total copy number 1): 292. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
